Gene-level copy-number profile of tumor specimen TCGA-AN-A0G0-01A from TCGA case TCGA-AN-A0G0, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 56.1 years (20,504 days).
Specimen TCGA-AN-A0G0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.ab6ead94-e5ae-4bfc-bbe3-8ecac5a98a54.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A0G0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate.
https://portal.gdc.cancer.gov/files/5b54ab41-179a-402b-8ac2-e74fc87aeab2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 2,832; copy number 2: 8,691; copy number 3: 33,710; copy number 4: 6,679; copy number 5: 4,474; copy number 6: 2,822; copy number 7: 315; copy number 11: 20; copy number 14: 131; copy number 15: 6; copy number 16: 2; copy number 18: 38; copy number 31: 47.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,178,589–22,214,672, 47 genes: IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 559 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,228,319–3,481,113, 38 genes, copy number 18: SKI, AL590822.3, MORN1, AL589739.1, AL513477.1, AL513477.2, RER1, PEX10, PLCH2, AL139246.1, AL139246.4, PANK4, HES5, AL139246.5, TNFRSF14-AS1, TNFRSF14, AL139246.2, AL139246.3, PRXL2B, MMEL1, MMEL1-AS1, TTC34, AC242022.2, AC242022.1, AL592464.2, AL592464.3, AL592464.1, AL589702.1, ACTRT2, PRDM16-DT, PRDM16, MIR4251, AL008733.1, AL512383.1, AL590438.1, AL354743.2, AL354743.1, ARHGEF16.
- chr1:229,087,114–236,604,516, 177 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr1:239,386,565–247,257,210, 158 genes, copy number 7–11 (within-gene range 1–11) (broad region; genes not listed).
- chr11:76,675,079–79,441,030, 55 genes, copy number 15–31 (within-gene range 5–31): AP001189.4, GUCY2EP, AP003119.1, TSKU, AP003119.2, AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1.
- chr17:26,981,694–29,057,216, 130 genes, copy number 14 (broad region; genes not listed).
- chr17:29,073,521–29,078,857, 1 gene, copy number 14: TIAF1.

Autosomal genes at a single copy (total copy number 1): 411. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
